Somatic mutation profile of tumor specimen TCGA-EM-A2CS-01A (aliquot TCGA-EM-A2CS-01A-11D-A19J-08) from TCGA case TCGA-EM-A2CS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, oxyphilic cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-EM-A2CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 146514f9-0401-4496-aa60-e8bd26b6d053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CS-10A (Blood Derived Normal), aliquot TCGA-EM-A2CS-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ce84a79-699e-4068-8238-a71c4a4c9c3b

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTL6B | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1230973901, COSV99355775; called by muse, mutect2
- ADPGK | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100295172, COSV61174029; called by muse, mutect2, varscan2
- BFAR | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs547915921, COSV99902081; called by muse, mutect2, varscan2
- KIF19 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs776277390, COSV100739193; called by muse, mutect2, varscan2
- PURA | c.331_332insA p.R111Qfs*90 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | catalogued as COSV100495805; called by mutect2, varscan2
- SLC27A3 | c.1801C>G p.P601A (on ENST00000271857; = p.P473A on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99670196; called by muse, mutect2
- TEAD1 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100532936; called by muse, mutect2, varscan2
- C2orf15 | c.189T>C p.T63= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100209103; called by muse, mutect2
- NOTCH4 | c.5787A>T p.I1929= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100901094; called by muse, mutect2
- SENP2 | c.658T>C p.L220= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV99957647; called by muse, mutect2, varscan2
